Surgical pathology report (de-identified scan), TCGA case TCGA-97-8174, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - NYU, specimen TCGA-97-8174-01A (Primary Tumor).

[page 1 of 13]
SURGICAL PATHOLOGY REPORT

COLLECTION DATE: [REDACTED]

SPECIMENS:

1. F/S R2 LYMPH NODE
2. F/S R4 LYMPH NODE
3. F/S L4 LYMPH NODE
4. F/S LUNG, RIGHT UPPER LOBE
5. RIB 5
6. STATION 10 LYMPH NODE
7. STATION 11 LYMPH NODE
8. STATION 7 LYMPH NODE
9. CYST WALL
- SEE ADDENDUM

Reason For Addendum #1: Molecular Studies

Reason For Addendum #2: Molecular Studies

Reason For Addendum #3: Biomarker Report

DIAGNOSIS:

1. LYMPH NODE, RIGHT LEVEL 2: BIOPSY

- THREE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/3).

2. LYMPH NODE, RIGHT LEVEL 4: BIOPSY

- THREE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/3).

3. LYMPH NODE, LEFT LEVEL 4: BIOPSY

- TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).

4. LUNG, RIGHT UPPER LOBE: LOBECTOMY

- ADENOCARCINOMA, PAPILLARY PREDOMINANT (7.0 CM), SEE NOTE.**
- THE BRONCHIAL AND VASCULAR MARGINS ARE FREE OF TUMOR.**
- SIX BENIGN LYMPH NODES (0/6).**

[page 2 of 13]
Note: The tumor consists of papillary (90%), lepidic (5%) and micropapillary (5%) components. Results of mutational studies will be reported in addenda.

5. RIB, 5TH: EXCISION

- BONE AND BONE MARROW WITH TRILINEAGE HEMATOPOEISIS.

6. LYMPH NODE, LEVEL 10: BIOPSY

- TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).

7. LYMPH NODE, LEVEL 11: BIOPSY

- FIVE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/5).

8. LYMPH NODE, LEVEL 7: BIOPSY

- TEN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/10).

9. LUNG, CYST: EXCISION

- BENIGN FIBROCONNECTIVE TISSUE AND ADIPOSE TISSUE WITH A SINGLE DILATED BRONCHIOLE.

Specimens: 1: F/S R2 LYMPH NODE

2: F/S R4 LYMPH NODE

3: F/S L4 LYMPH NODE

4: F/S LUNG, RIGHT UPPER LOBE

5: RIB 5

6: STATION 10 LYMPH NODE

7: STATION 11 LYMPH NODE

8: STATION 7 LYMPH NODE

9: CYST WALL

LUNG: Resection

SPECIMEN

Specimen: Lobe(s) of lung (specify)

Right upper lobe

Procedure: Lobectomy

Specimen Integrity: Intact

Specimen Laterality: Right

Tumor Site: Upper lobe

Tumor Focality: Unifocal

TUMOR

Histologic Type: Adenocarcinoma, mixed subtype

Histologic Grade: G2: Moderately differentiated

EXTENT

Tumor Size: Greatest dimension (cm)

7cm

Additional Dimension (cm): 6cm x 3.5cm

[page 3 of 13]
Visceral Pleura Invasion: Not identified

Tumor Extension: Not applicable

MARGINS

Bronchial Margin

Bronchial Margin Involvement by Invasive Carcinoma: Uninvolved by invasive carcinoma

Vascular Margin: Uninvolved by invasive carcinoma

ACCESSORY FINDINGS

Lymph-Vascular Invasion: Not identified

STAGE (pTNM)

TNM Descriptors: Not applicable

Primary Tumor (pT): pT2b: Tumor greater than 5 cm, but 7 cm or less in greatest dimension

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Number Examined

31

Number Involved

0

Distant Metastases (pM): Not applicable

ADDITIONAL NON-TUMOR

Tumor Associated Atelectasis or Obstructive Pneumonitis:

Extends to the hilar region but does not involve entire lung

[REDACTED]

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

[REDACTED] ex-smoker (40 pack-years) with hx of asbestos exposure, now with a 6.1 cm RUL mass.

MACROSCOPIC DESCRIPTION:

The specimen is received in nine parts, each labeled with the patient's name.

1. Part one is labeled 'R2 lymph node '. It consists of three lymph nodes measuring 0.5 x 0.4 x 0.2 cm (inked blue), 0.6 x 0.3 x 0.2 cm (inked green) and 0.2 x 0.2 x 0.2 cm (inked black). Entirely submitted for frozen section.

2. Part two is labeled ' R4 lymph node'. It consists of three lymph nodes measuring 0.7 x 0.2 x 0.2 cm, 0.7 x 0.7 x 0.3 cm and 0.5 x 0.3 x 0.2 cm. Entirely submitted for frozen section.

3. Part three is labeled 'L4 lymph node'. It consists of two lymph nodes measuring 0.5 cm and 0.5 cm in greatest dimension. Entirely

[page 4 of 13]
submitted for frozen section.

4. Part four is received fresh, labeled 'right upper lobe'. It consists of a lobectomy specimen of right upper lobe of lung, weighing 318 grams, measuring 16 x 12 x 6 cm. The pleura appears smooth tan and glistening. There are two staple lines, the longest one measuring 15 cm in length and the shortest measures 5 cm in length. The staple lines are inked black. An ill-defined nodular tan-grey white nodule is noted but is previously opened and measures 7 x 6 x 3.5 cm. The distance of the nodule from the bronchial margin is 0.3 cm and from the vascular margin is 0.1 cm. The remaining lung parenchyma appears unremarkable. A single hilar lymph node is identified that measures 2.5 x 2 x 1 cm. Multiple parenchymal lymph nodes are identified. A frozen section evaluation is done on the tumor nodule. These are the indicated sections are submitted as follows:

5. Part five is labeled 'rib 5 '. It consists of fragments of hemorrhagic rib measuring 1.3 x 1 x 0.7 cm. The specimen is sectioned. Representative sections are submitted after decalcification.

6. Part six is labeled 'station 10 lymph node '. It consists of two pieces of tan-red soft tissue measuring 1.5 x 1.5 x 0.5 cm and 1.2 x 0.5 x 0.5 cm. Entirely submitted.

7. Part seven is labeled 'station 11 lymph node '. It consists of one piece of tan-red soft tissue measuring 2.5 x 1.5 x 0.7 cm. Entirely submitted.

8 Part eight is labeled 'station 7 lymph node '. It consists of a piece of tan-red soft tissue measuring 2.5 x 2.0 x 1 cm. Entirely submitted.

9. Part nine is labeled 'cyst wall '. It consists of a piece of tan-red soft tissue measuring 1.5 x 1.0 x 0.3 cm. Entirely submitted.

SUMMARY OF SECTIONS:

1A three lymph nodes

2A three lymph nodes

3A two lymph nodes

[page 5 of 13]
4A frozen section, tumor nodule
4B-4D staple line
4E vascular margin
4F bronchial margin
4G hilar lymph nodes
4H tumor in relation to bronchus
4I tumor in relation to lung
4J tumor with normal lung
4K tumor with adjacent bronchus and vessels
4L tumor with adjacent bronchus
4M-4O tumor nodule
4P tumor with adjacent normal lung parenchyma
4Q-4T tumor nodule
4U parenchymal lymph nodes
4V normal lung parenchyma
5A representative section
6A-6B total
7A one lymph node bisected
7B four lymph nodes
7C-7D remainder of tissue
8A-8B total
9A total

SPECIAL PROCEDURES:
decalcification

INTRA - OPERATIVE CONSULTATION:

1. F/S R2 LYMPH NODE: (Frozen Section)
- 3 lymph nodes negative for carcinoma
2. F/S R4 LYMPH NODE (Frozen Section)
- 3 lymph nodes negative for carcinoma
3. F/S L4 LYMPH NODE: (Frozen Section)

[page 6 of 13]
- 2 lymph nodes negative for carcinoma

Results reported by [REDACTED] and
repeat-back provided by [REDACTED]

4. F/S LUNG, RIGHT UPPER LOBE: (Frozen Section)
- adenocarcinoma with predominantly papillary features

Results reported by [REDACTED] and repeat-back
provided by [REDACTED]

ADDENDUM # 1 FOR MOLECULAR TESTS:

EGFR, KRAS and ALK (FISH) was sent on [REDACTED] for patient [REDACTED]. The test is to be performed on tissue from case [REDACTED]. The case report, slides, and blocks for the cited accession number were retrieved from archives. The pathologist whose signature appears below reviewed the original pathology report, examined candidate H&E slides, and selected block 4M appropriate to the specifications of the ordered molecular analysis. 1 H&E and 9 unstained slides were prepared and forwarded to [REDACTED] where the subject molecular test will be performed. An addendum report will be issued when the results of this molecular test are available.

[page 7 of 13]
Addendum #1 performed by

Electronically signed

ADDENDUM #2:

MOLECULAR ONCOLOGY

KRAS MUTATION ANALYSIS

Referring Physician

Body Site: Lung

Specimen Type: Slides

Clinical Data: Adenocarcinoma

RESULTS: Wild-type gene.

INTERPRETATION: No mutations were identified at codons 12 and 13 of the KRAS gene.

COMMENT:

Mutations in the KRAS gene are reported to be associated with poor prognosis, and resistance to targeted tyrosine kinase inhibitor therapies in patients with non-small-cell lung cancer (NSCLC). KRAS mutations occur in 15-30% of NSCLC patients and are strongly associated with adenocarcinoma and smoking history.

This assay analyzes codons 12 and 13 in exon 2 of the KRAS gene; based on the current literature, approximately 98% of mutations are expected to occur in these codons. The analytical sensitivity of the assay is approximately 10%; thus mutations present in a low percentage of cells may not be detected. This test is validated for use in identifying KRAS codon 12 and codon 13 mutations in fresh, frozen, or formalin-fixed paraffin embedded tissue. In particular the test performance has been established in samples of colorectal cancer and non-small cell lung carcinoma which harbor these mutations, although several other tissues are also known to harbor KRAS mutations (e.g. tumors of pancreas, bile duct, ovary, appendix, etc.).

Analysis of EGFR mutation or gene amplification status may provide additional information regarding this patient's probability of response to targeted tyrosine kinase inhibitor therapies, if clinically indicated. See references.

[page 8 of 13]
METHOD/LIMITATIONS:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exon 2 of the KRAS gene. PCR products are subjected to single nucleotide primer extension to detect mutations at codons 12 and 13; primer extension products are analyzed using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

[REDACTED]

This test was developed and its performance characteristics determined by [REDACTED]. The laboratory is regulated under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be used only in the context of other diagnostic tests or clinical work-up related to treatment decisions.

[REDACTED]

Electronically signed by: [REDACTED] Date:

[REDACTED]

Testing performed at

[REDACTED]

[page 9 of 13]
EGFR Mutation Analysis

[REDACTED]

Referring Physician: [REDACTED]

Body Site: Lung

Clinical Data: Adenocarcinoma

RESULTS: No mutation detected.

INTERPRETATION: No mutations were identified in the sample provided for analysis. Fewer than 5% of non-small cell lung carcinoma patients without identifiable mutations are reported to be responsive to EGFR tyrosine kinase inhibitor therapies.

COMMENT: Forty percent (40%) or more tumor cellularity is optimal for this mutation analysis. The sample submitted showed 30% tumor cellularity upon pathologist review.

A frequently occurring sequence change 2361G>A (Q787Q) was identified. This polymorphism is known not to have clinical significance.

Mutations in the tyrosine domain of the epidermal growth factor receptor (EGFR) gene are reported to be associated with differential responsiveness or resistance to EGFR tyrosine kinase inhibitor (TKI) therapies. The objective response rate among patients with a sensitizing mutation ranges from 55 to 82%.

This assay analyzes exons 18-21 of the EGFR tyrosine kinase domain; based on the current literature, most mutations in non-small-cell lung carcinoma (NSCLC) are expected to occur in these exons. Mutations present in less than 10-20% of extracted DNA may not be detected by this method. Mutation status in a sample may change during tumor progression or the course of therapy; therefore, this result cannot be used to infer the presence or absence of a mutation in another sample or sub-sample obtained from this tumor.

This test is validated for non-small cell lung carcinoma. The clinical significance and utility of this test in other tumor types is unknown.

METHOD/LIMITATION:

[page 10 of 13]
Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the samples, quantified and amplified by polymerase chain reaction (PCR) using primers to exons 18-21 of the EGFR gene. PCR products are analyzed by bi-directional direct DNA sequencing using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

[REDACTED]

DISCLAIMER:

This test was developed and its performance characteristics determined by [REDACTED]. It has not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigation or for research. The laboratory is regulated under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be used only in the context of other diagnostic tests or clinical work-up related to treatment decisions.

[REDACTED]

Electronically signed by:
Date:

[REDACTED]

Addendum #2 performed by

[REDACTED]

[page 11 of 13]
ADDENDUM 3:

Fluorescence In-Situ Hybridization (FISH)

Referring Physician

Body Site: Lung

Clinical Data: Adenocarcinoma

INTERPRETATION:

Negative for a rearrangement involving the ALK gene.

Probe #Nuclei Examined % Positive Nuclei %

Control values

2p23(ALK)V 100 0 <15.0

A total of 100 cells were scored.

FINDINGS: FISH was performed on paraffin embedded tissue sections using dual color break-apart probe (Abbott Molecular) to the ALK gene at 2p23. This probe flanks the entire gene. If a rearrangement involving ALK is present, inversion or translocation, one of the two probe signals separates as one red (orange) and one green signal. In this specimen, separated signals were present in 0.5% of the nuclei scored. Based on laboratory validation data, these results are within the normal limits.

COMMENTS: Three to four copies of ALK were observed in 27.0% of cells. This gain of intact ALK fusion hybridization signals represents an aneuploid population with extra copies of chromosomes 2/2p ALK region. Additional copies of ALK are not uncommon in NSCLCs, although the significance of extra copies of the ALK gene in lung carcinoma is unclear at this time (

[page 12 of 13]
[REDACTED]

ISCN RESULTS: nuc ish(ALKx3 4)[27/100]

This test was developed and its performance characteristics determined by [REDACTED]. It has not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. The laboratory is regulated under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical testing.

[REDACTED]

Electronically [REDACTED]
[REDACTED]

[REDACTED]

Addendum #3 performed by [REDACTED]

Electronically signed [REDACTED]

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

[page 13 of 13]
This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by [REDACTED] Department of Pathology.

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file a617206d-32c6-4635-a299-842d703ff79a (TCGA-97-8174.F71782A0-0D9F-486E-9E17-CD5FF92D44D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).